Somatic mutation profile of tumor specimen 0DFYQS from CCDI case PBBSRJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 10.2 years (3,740 days).
Specimen 0DFYQS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94bb6428-0720-45e6-8d2c-00bf038521a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff1ad527-75d3-4ef9-b846-71e1505f4784

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COQ3 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 219/443 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs868841248; called by muse, mutect2, varscan2
- DSPP | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2
- ERVFRD-1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 38/560 reads (7%) | called by muse, mutect2
- PTCHD1 | c.405G>C p.T135= | Silent (SNP) | VAF 27/535 reads (5%) | called by muse, mutect2
- ARMCX3 | c.-54C>T | 5'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, varscan2
